Somatic mutation profile of tumor specimen TCGA-KN-8423-01A (aliquot TCGA-KN-8423-01A-11D-2310-10) from TCGA case TCGA-KN-8423, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 44.7 years (16,335 days).
Specimen TCGA-KN-8423-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc53bae0-984f-4cbc-ae0c-2a5522b02200.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8423-11A (Solid Tissue Normal), aliquot TCGA-KN-8423-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f4c155d-7b17-4cd0-b71e-5b12970afaf3

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 38/65 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DNAH9 | c.9989A>G p.D3330G | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV99306771; called by muse, mutect2
- IQUB | c.1282G>C p.A428P | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.405); catalogued as COSV100227222; called by muse, mutect2, varscan2
- NMT2 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV100975589; called by muse, mutect2
- PTPRA | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV99400208; called by muse, mutect2
- UGT3A1 | c.887T>A p.V296D | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99955021; called by muse, mutect2, varscan2
- UPP1 | c.892_895dup p.V299Afs*30 | Frame Shift Ins (INS) | VAF 24/43 reads (56%) | called by mutect2, pindel, varscan2
- TAB3 | c.1804+504_1804+505del | Intron (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel, varscan2
